Somatic mutation profile of tumor specimen 0DVVL3 from CCDI case PBCNCH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 16.1 years (5,879 days).
Specimen 0DVVL3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11a86161-6f27-4538-86a8-a591c7529836.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVVME (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94147076-ac83-4bfd-b3d8-d20e042adfbb

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 427/1065 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NECTIN4 | c.649A>C p.N217H | Missense Mutation (SNP) | VAF 140/358 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63512179; called by muse, mutect2, varscan2
- ATP13A3 | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 37/1174 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2
- DNLZ | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN2 | c.8343C>A p.D2781E | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.142); called by muse, mutect2
- PGM2L1 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 191/952 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIMP2 | c.80G>T p.C27F | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- FMN2 | c.4630C>A p.R1544= | Silent (SNP) | VAF 183/1064 reads (17%) | catalogued as COSV60417350; called by muse, mutect2, varscan2
- GOLM2 | c.351G>A p.S117= | Silent (SNP) | VAF 166/472 reads (35%) | catalogued as rs780302499, COSV55462203; called by muse, mutect2, varscan2
- OBSL1 | c.4107C>G p.L1369= | Silent (SNP) | VAF 20/408 reads (5%) | called by muse, mutect2
- DPAGT1 | c.162-24C>T | Intron (SNP) | VAF 69/176 reads (39%) | catalogued as rs181437941; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 20/272 reads (7%) | called by muse, mutect2
- TMEM25 | c.805+12A>T | Intron (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
